Somatic mutation profile of tumor specimen MP2PRT-PAVWVM-TMP1-A (aliquot MP2PRT-PAVWVM-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVWVM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,389 days).
Specimen MP2PRT-PAVWVM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abf3be44-828f-4370-9180-01176d6c670e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWVM-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWVM-NM1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e83050b4-d3f1-4a41-8028-73d903141493

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 79/216 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- SORCS1 | c.2206C>T p.R736* | Nonsense Mutation (SNP) | VAF 45/602 reads (7%) | catalogued as rs1267517816, COSV53890752; called by muse, mutect2
- NFYB | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- PKHD1 | c.10010G>T p.G3337V | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKHD1 | c.10009G>T p.G3337* | Nonsense Mutation (SNP) | VAF 81/283 reads (29%) | called by muse, mutect2, varscan2
- FN1 | c.2913C>G p.V971= | Silent (SNP) | VAF 180/444 reads (41%) | called by muse, mutect2, varscan2
